Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A046, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A046-01A (Primary Tumor).

TSS Patient ID

Case #: ' DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement Anatomic Site: **Right Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **2**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

100-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9

lw

10/21/11

Source: NCI Genomic Data Commons file 5c0969d9-bfa6-4813-a830-f02819105a6e (TCGA-AN-A046.1304FB17-A20A-4EBC-9CC8-1554808AC1F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).